Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GE-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

A) RIGHT SHOULDER, , SKIN ELLIPSE:

MALIGNANT SPINDLE CELL NEOPLASM IN DERMIS AND SUBCUTANEOUS TISSUE, FOCALLY PRESENT AT DEEP TISSUE EDGE AND IN INFERIOR TIP.

TUMOR SIZE: 58 X 50 MM (AS PER GROSS DESCRIPTION)

Tumor borders infiltrative.

See comment.

ICD-O-3

Melanoma, spindle cell NOS
8772/3

B) ADDITIONAL MEDIAL MARGIN, SKIN EXCISION:

Skin and subcutis; melanoma is not identified.

Site: R Shoulder, skin
044.6

C) ADDITIONAL LATERAL MARGIN, SKIN EXCISION:

Skin and subcutis; melanoma is not identified.

11/27/13

COMMENT

(A) Immunohistochemical studies were performed and demonstrate the tumor cells to be strongly and diffusely positive for S100 (nuclear and cytoplasmic), Sox-9 (nuclear) and CD34. The tumor cells are negative with an anti-melanocytic cocktail (HMB45, anti-MART1 and anti-tyrosinase) and with antibodies for MITF. This immunohistochemical phenotype is similar to that reported in this patient's lung metastasis (see and is thus, consistent with melanoma.

This case was studied and discussed at the dermatopathology faculty conference and separately with

CONSULTANT(S)

GROSS DESCRIPTION

(A) SOFT TISSUE RESECTION MELANOMA OF RIGHT SHOULDER, SHORT – SUPERIOR, LONG – LATERAL. SCALE FOR PROTOCOL – An oval shaped, dark tan skin and soft tissue excision (7.3 x 6.2 x 4.4 cm), oriented by the surgeon with a short stitch marking superior and a long stitch marking lateral. Serial sections of the specimen reveal a light tan and light gray homogeneous, solid well circumscribed mass (5.8 x 5 x 4.2 cm), arising out of the skin and located at 0.7 cm from superior, 0.6 cm from lateral, 0.8 cm from inferior, 0.2 cm from medial and 0.2 cm from deep. The rest of the specimen is grossly unremarkable. Please note that the majority of the specimen was provided for and due to the initial sectioning we are submitting perpendicular sections of the lateral and medial margin closest to the tumor. The remainder of the specimen appears grossly unremarkable.

INK CODE: Blue – lateral aspect, yellow – medial aspect.

SECTION CODE: A1, superior resection margin submitted en face; A2-A3, tumor in closest lateral resection margin, perpendicular section; A4, inferior resection margin en face; A5-A6, tumor and closest medial resection margin, perpendicular sections; A7, tumor and deep margin; A8, tumor in skin; A9-A10, representatives of tumor.

(B) ADDITIONAL MEDIAL MARGIN, STITCH AT MARGIN, PERMANENT – A dark tan, unremarkable skin, triangular in shape excision (5 x 2.5 x 1.8 cm), with a stitch marking the margin. The specimen was inked and new margin was shaved.

INK CODE: Blue – new margin, yellow – for orientation purposes marking the true end tip of the specimen.

SECTION CODE: B1-B3, true margin entirely submitted en face.

(C) ADDITIONAL LATERAL MARGIN, STITCH AT MARGIN – A triangular shape portion of dark tan, unremarkable skin (4.6 x 1.5 x 1.5 cm), oriented by the surgeon with a stitch marking the true margin. The true margin was inked and shaved from the specimen.

INK CODE: Blue – true margin, yellow – both end tips of the specimen (for orientation purposes only).

SECTION CODE: C1-C2, new margin entirely submitted en face.

BIOMARKER TESTING

The following material is selected for biomarker testing:

Primary

Tumor Block: A9

Normal Block: A1

Tumor Block: A8

Normal Block: B3

[page 2 of 2]
CLINICAL HISTORY
None given.

SNOMED CODES

M-87206 M-78060 M-78060

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Case is [unclear]		

Source: NCI Genomic Data Commons file 9dae0004-42f8-4c3d-949d-2912406eaabe (TCGA-D3-A8GE.4C9A9F9A-CD40-4ED3-9999-030256E1BB57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).